Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A2G7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A2G7-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

ICD-0-3

Carcinoma, serous, NOS 8441/3

Site: Endometrium C54.1

lw
6/3/11

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 J1 K1 L1 M1 N1 O1 P1 Q1
R1 S1 B1
B2 B3 B4 B5 B6 B7 B8 B9 T1 U1 V1 C1 C2 C3 C4 C5 C6 C7 C8
C9 C10 C11
C12 C13 C14 D1 E1 F1 G1 H1 I1
Uterus, right ovary (2.0 x 1.0 x 1.0 cm) with 7.0 cm
segment of
right fallopian tube, and left ovary (2.0 x 1.0 x 1.0 cm)
with 5.0
cm segment of left fallopian tube together weighing 205.0
grams;
tissue from the omentum (biopsy, 1.3 x 1.0 x 0.4 cm);
separately
submitted portion of omentum (34.0 x 24.0 x 2.0 cm); right
and left
pelvic lymph nodes; right and left para-aortic lymph nodes
above and
below the inferior mesenteric artery; right gonadal
vessels (4.5 cm
in length); left gonadal vessels (6.0 cm in length); and
staging
biopsies [right colic gutter, right pelvic sidewall, right
diaphragm, cul de sac, left colic gutter, left pelvic
sidewall,
small bowel serosa, large bowel serosa, bladder
peritoneum, small
bowel mesentery, and large bowel mesentery (all ranging in
size from
0.2 cm to 1.5 cm in greatest dimension)].

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; radical
hysterectomy
and bilateral salpingo-oophorectomy: FIGO grade III (of
III) serous
carcinoma is identified involving an endometrial polyp
(4.0 x 3.0 x
3.0 cm) in the upper endometrial cavity. There is a
submucosal
leiomyoma in the lower uterine segment. The surface
endometrium is

[page 2 of 3]
diffusely involved by serous carcinoma. Random sections of the endometrium show a mixture of serous carcinoma and FIGO grade I (of III) endometrioid carcinoma. There is focal superficial invasion (0.2 cm, total wall thickness, 2.5 cm). There is no lymphovascular space involvement. The endocervix is uninvolved. The cervix is unremarkable. There is a 1.5 cm simple cyst in the left ovary. The right ovary is atrophic. The fallopian tubes are atrophic.

Omentum, biopsy: Negative for tumor.

Omentum, omentectomy: Negative for tumor.

Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (12 external iliac, 1 internal iliac, 6 common iliac, 8 obturator) are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (7 external iliac, 1 internal iliac, 4 common iliac, 10 obturator) are negative for tumor.

Lymph nodes, right and left para-aortic above and below the inferior mesenteric artery, lymphadenectomies: Multiple para-aortic lymph nodes above the inferior mesenteric artery (3 right, 7 left) are negative for tumor. Multiple para-aortic lymph nodes below the inferior mesenteric artery (6 right, 7 left) are negative for tumor.

Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor.

[page 3 of 3]
Soft tissue; right colic gutter, right pelvic sidewall,
right
diaphragm, cul de sac, left colic gutter, left pelvic
sidewall,
small bowel serosa, large bowel serosa, bladder
peritoneum, small
bowel mesentery, and large bowel mesentery; staging
biopsies:
Negative for tumor, all sites.

Source: NCI Genomic Data Commons file 4dc819d3-cfb2-4f6f-9b40-f4a9124295ee (TCGA-D1-A2G7.5D25FD0B-EEE9-435C-82C7-BC44B0758A14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).